Somatic mutation profile of tumor specimen TCGA-LN-A49R-01A (aliquot TCGA-LN-A49R-01A-11D-A247-09) from TCGA case TCGA-LN-A49R, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 46.8 years (17,109 days).
Specimen TCGA-LN-A49R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c38748e4-0de6-4159-8ee0-d2828e8c4293.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49R-10A (Blood Derived Normal), aliquot TCGA-LN-A49R-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67891a99-bfe6-4ae8-b786-1a70172009ea

The open-access MAF lists 118 somatic variants for this specimen: 98 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 18, Nonsense Mutation 5, Frame Shift Ins 5, Splice Site 3, Intron 2, Frame Shift Del 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 10/11 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 20/38 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 39/42 reads (93%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- AGAP1 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58322439; called by muse, mutect2, varscan2
- AMY2B | c.671C>A p.A224E | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); catalogued as rs749735334; called by muse, mutect2, varscan2
- APOB | c.11945C>T p.A3982V | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs747463777, COSV51931870; called by muse, mutect2, varscan2
- APOB | c.5119G>A p.E1707K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558565287; called by muse, mutect2, varscan2
- CCDC39 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs769886847, COSV99867021; called by muse, mutect2, varscan2
- CIAPIN1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200237459, COSV67953414; called by muse, mutect2, varscan2
- CLEC18B | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1490861771; called by mutect2, varscan2
- COL7A1 | c.5503G>T p.D1835Y | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60394353; called by muse, mutect2, varscan2
- DTL | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287076244; called by muse, mutect2, varscan2
- FAM13B | c.2683A>G p.I895V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1561720545; called by muse, mutect2, varscan2
- GP2 | c.1481T>C p.V494A (on ENST00000381362 / NM_001007240.3; = p.V491A on NM_001502.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as rs1479289551; called by muse, mutect2, varscan2
- INTU | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs758759703; called by muse, varscan2
- LMAN2L | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99383600; called by muse, mutect2, varscan2
- LMNB2 | c.1200G>C p.E400D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs764433406; called by muse, mutect2, varscan2
- LRRC37B | c.2380G>T p.G794W | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as rs1368700587, COSV58952437; called by muse, mutect2, varscan2
- MYO18A | c.1529A>G p.H510R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as rs1385899475; called by muse, mutect2, varscan2
- OR10G7 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs150421981; called by muse, mutect2, varscan2
- OR52L1 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs199647565; called by muse, mutect2, varscan2
- PTCH1 | c.994A>T p.R332* | Nonsense Mutation (SNP) | VAF 23/29 reads (79%) | catalogued as COSV59486569; called by muse, mutect2, varscan2
- RBAK | c.1776G>C p.E592D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV62330834; called by muse, mutect2, varscan2
- REV3L | c.4679A>G p.N1560S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775832892; called by mutect2, varscan2
- SEMA3F | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.914); catalogued as COSV50029045; called by muse, mutect2, varscan2
- SLC6A18 | c.694G>C p.G232R | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104395643; called by muse, mutect2, varscan2
- SMCHD1 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs371805529; called by muse, mutect2, varscan2
- SMG7 | c.1228A>G p.I410V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs745521666; called by muse, mutect2, varscan2
- SRPK1 | c.1646A>G p.Y549C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368604697; called by muse, varscan2
- TAS2R4 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV56093726; called by mutect2, varscan2
- TECRL | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV67085419; called by muse, mutect2, varscan2
- THSD7B | c.3245G>T p.R1082L (on ENST00000272643; = p.R1080L on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.496); catalogued as COSV55655087; called by muse, mutect2, varscan2
- TMIGD1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1180519959; called by muse, mutect2, varscan2
- TRAF7 | c.1629C>T p.I543= | Splice Region (SNP) | VAF 12/31 reads (39%) | catalogued as rs946553688; called by muse, mutect2, varscan2
- ZNF394 | c.1589G>C p.C530S | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61794266; called by muse, mutect2, varscan2
- ALDH1L1 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AMY2B | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7355C>G p.S2452C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ARHGAP21 | c.4411A>G p.I1471V | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND2 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- CDK18 | c.1268+1G>T p.X423_splice (on ENST00000506784 / NM_212503.3; = p.X393_splice on NM_002596.4) | Splice Site (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2
- CDKL3 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CEL | c.1306A>G p.T436A (on ENST00000673714; = p.T433A on NM_001807.6) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- CENPO | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CEP290 | c.4747A>T p.I1583F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- COL17A1 | c.4401_4402dup p.G1468Vfs*45 | Frame Shift Ins (INS) | VAF 24/38 reads (63%) | called by mutect2, pindel, varscan2
- CRACR2B | c.427dup p.E143Gfs*209 (on ENST00000525077 / NM_001286606.2; = p.E143Gfs*147 on NM_173584.4) | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- CSMD3 | c.2713G>T p.V905L (on ENST00000297405 / NM_001363185.1; = p.V801L on NM_052900.3) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DARS2 | c.801T>G p.D267E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAZAP2 | c.105dup p.T36Yfs*76 | Frame Shift Ins (INS) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- DGCR2 | c.329-2A>G p.X110_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- DIO2 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- DMD | c.3590T>A p.V1197D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by mutect2, varscan2
- DNAJC13 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYSF | c.5502G>T p.K1834N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FAM83F | c.1214_1215insGGCTC p.H406Afs*8 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- FBXO21 | c.1532A>C p.H511P (on ENST00000330622 / NM_033624.3; = p.H504P on NM_015002.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXO9 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- FBXW12 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FRYL | c.4412A>T p.Y1471F | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GGA2 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GINM1 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRM8 | c.1356T>A p.N452K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- H1-4 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2
- HSD3B2 | c.406del p.I136Sfs*38 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- IGSF9B | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- KMT2D | c.9493dup p.D3165Gfs*11 | Frame Shift Ins (INS) | VAF 7/18 reads (39%) | called by mutect2, pindel, varscan2
- MAP2K5 | c.553C>G p.H185D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13L | c.6013A>G p.I2005V | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MXD1 | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- NPAP1 | c.3067A>C p.S1023R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NSMF | c.1201G>C p.G401R (on ENST00000371475 / NM_001130969.3; = p.G399R on NM_015537.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDCD1 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OXNAD1 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PDCD2 | c.608T>C p.M203T | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF20L1 | c.195del p.L65Ffs*9 | Frame Shift Del (DEL) | VAF 55/111 reads (50%) | called by mutect2, pindel, varscan2
- PHIP | c.2368C>A p.Q790K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- POP1 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.03); called by muse, mutect2
- PPFIA3 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PTPRO | c.3154C>T p.P1052S (on ENST00000281171 / NM_030667.3; = p.P1024S on NM_002848.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RACGAP1 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RMND5B | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- RNF169 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPP38 | c.222A>T p.K74N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SACS | c.5618A>G p.Y1873C | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SV2C | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TAF5 | c.2237A>G p.D746G | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TANK | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TCHH | c.4743C>A p.F1581L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TDRD3 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLR1 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMCC1 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRGJP2 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.91805_91819del p.K30602_E30606del (on ENST00000591111; = p.K23178_E23182del on NM_003319.4) | In Frame Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- UBE2L6 | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- UGGT1 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF134 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF385D | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- C7orf31 | c.675A>G p.V225= | Silent (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- CAND1 | c.2598A>T p.S866= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- CMYA5 | c.591C>A p.T197= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1405715528; called by muse, mutect2, varscan2
- COBL | c.2643C>G p.V881= | Silent (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- EGR2 | c.159A>C p.G53= | Silent (SNP) | VAF 14/15 reads (93%) | called by muse, mutect2, varscan2
- GOLM1 | c.813G>A p.P271= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as rs778114709, COSV57414030; called by muse, mutect2, varscan2
- HIVEP1 | c.5328C>T p.D1776= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs539525903; called by muse, varscan2
- HMCN1 | c.12258G>A p.K4086= | Silent (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- ITGAX | c.1236C>G p.A412= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- MAGEC2 | c.42C>T p.N14= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as rs770018745, COSV99909451; called by muse, varscan2
- NF1 | c.2319C>T p.N773= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100647234; called by muse, mutect2, varscan2
- OR11A1 | c.897T>C p.H299= | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- PLEKHG6 | c.1350G>A p.K450= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- SEMA6C | c.2725C>T p.L909= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs1435128873; called by muse, mutect2, varscan2
- SLC14A1 | c.144G>A p.Q48= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- SLC38A7 | c.1347C>T p.G449= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs766024243; called by muse, mutect2, varscan2
- TAS1R3 | c.99G>T p.G33= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- TNR | c.936C>T p.C312= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs754692586; called by muse, varscan2
- ITGB1 | c.2331+1252A>G | Intron (SNP) | VAF 22/31 reads (71%) | catalogued as rs1170565844; called by muse, mutect2, varscan2
- NTNG1 | c.1087+10918G>T | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
